Gene-level copy-number profile of tumor specimen HCM-STAN-1113-C18-01A from HCMI case HCM-STAN-1113-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 68.9 years (25,168 days).
Specimen HCM-STAN-1113-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24368539-0a4d-4084-91db-e841da73bc61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-1113-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/a4d79fd8-9670-470a-adc5-7cbe2cef09af

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 318; copy number 2: 4,819; copy number 3: 33,074; copy number 4: 18,676; copy number 5: 57; copy number 6: 1,429; copy number 7: 2; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr10:79,825,902–79,827,602, 1 gene (within-gene range 0–3): AL135925.1.
- chr14:105,583,731–105,588,395, 1 gene: IGHA2.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,100,236–90,100,738, 1 gene, copy number 10: IGKV1D-16.
- chr2:90,121,786–90,122,564, 1 gene, copy number 7: IGKV2D-14.
- chr2:90,172,802–90,173,414, 1 gene, copy number 7: IGKV3D-11.

Autosomal genes at a single copy (total copy number 1): 318. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
